Somatic mutation profile of tumor specimen TCGA-3B-A9HO-01A (aliquot TCGA-3B-A9HO-01A-11D-A387-09) from TCGA case TCGA-3B-A9HO, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 75.7 years (27,664 days).
Specimen TCGA-3B-A9HO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42136453-b541-4344-acd9-136771bc3617.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3B-A9HO-10A (Blood Derived Normal), aliquot TCGA-3B-A9HO-10A-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f234c32a-3312-4e66-a709-5a2ecb7538ba

The open-access MAF lists 51 somatic variants for this specimen: 37 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 34, Silent 14, Frame Shift Ins 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAD10 | c.1320G>A p.M440I | Missense Mutation (SNP) | VAF 71/786 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100563804; called by muse, mutect2
- ANAPC4 | c.338T>A p.M113K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100193800; called by muse, mutect2, varscan2
- ARID3A | c.346G>T p.D116Y | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.462); catalogued as COSV99708237; called by muse, mutect2, varscan2
- ARRDC4 | c.1247T>G p.F416C | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); catalogued as COSV99164307; called by muse, mutect2
- ATP1A3 | c.1810G>A p.D604N (on ENST00000545399 / NM_001256214.2; = p.D591N on NM_152296.5) | Missense Mutation (SNP) | VAF 65/116 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as COSV100131950; called by muse, mutect2, varscan2
- CLCN4 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV101073632; called by muse, mutect2
- COBL | c.2163C>A p.D721E | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99471247; called by muse, mutect2
- EEA1 | c.509C>G p.T170S | Missense Mutation (SNP) | VAF 207/561 reads (37%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.97); catalogued as COSV100467061; called by muse, mutect2, varscan2
- FCGR2A | c.209G>A p.S70N (on ENST00000271450 / NM_001136219.3; = p.S69N on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/302 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99614964; called by muse, varscan2
- FCGR2A | c.311G>A p.C104Y (on ENST00000271450 / NM_001136219.3; = p.C103Y on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/290 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99614966; called by muse, varscan2
- FEZF1 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.059); catalogued as rs1301812506, COSV100484399; called by muse, mutect2, varscan2
- FTMT | c.365A>T p.E122V | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100360223, COSV100360495; called by muse, mutect2, varscan2
- GGT1 | c.754G>C p.D252H | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99958539; called by muse, mutect2, varscan2
- H3C10 | c.227C>G p.A76G | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.902); catalogued as COSV100297479; called by muse, mutect2
- JSRP1 | c.235G>C p.G79R | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV55558174, COSV99678271; called by muse, mutect2
- KDM4B | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV50280316; called by muse, mutect2, varscan2
- KIF19 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs143225781; called by muse, mutect2, varscan2
- MAGEB18 | c.1004C>T p.T335M | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs762230735, COSV57463911; called by muse, mutect2, varscan2
- OOEP | c.418G>C p.D140H | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.366); catalogued as COSV100949788; called by muse, mutect2, varscan2
- OR4F6 | c.376A>T p.I126L | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.167); catalogued as COSV100186796, COSV61027844; called by muse, mutect2, varscan2
- PCDHA6 | c.1340A>C p.D447A | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100971221; called by muse, mutect2, varscan2
- PRB4 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated, low confidence (0.79); PolyPhen possibly damaging (0.839); catalogued as COSV54399861; called by muse, mutect2, varscan2
- PREX2 | c.1712G>A p.G571E | Missense Mutation (SNP) | VAF 45/361 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.893); catalogued as COSV55798060; called by muse, mutect2, varscan2
- PRR5L | c.664C>A p.L222I | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.254); catalogued as COSV100286816; called by muse, mutect2, varscan2
- PXDNL | c.2087C>T p.S696F | Missense Mutation (SNP) | VAF 64/106 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs749122999, COSV100681335, COSV100682000, COSV100687305; called by muse, mutect2, varscan2
- SEMA5B | c.2861C>T p.T954M | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs1560277290, COSV52094376; called by muse, mutect2, varscan2
- SHC3 | c.624G>T p.M208I | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV101011864; called by muse, mutect2, varscan2
- TCTN1 | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 19/396 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV100885824; called by muse, mutect2
- TRPM2 | c.2496C>G p.I832M | Missense Mutation (SNP) | VAF 150/438 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as rs750090816, COSV100308191; called by muse, mutect2, varscan2
- TTLL2 | c.1604C>A p.T535N | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.122); catalogued as COSV99514382; called by muse, mutect2, varscan2
- TTN | c.47015C>A p.P15672Q (on ENST00000591111; = p.P8248Q on NM_003319.4) | Missense Mutation (SNP) | VAF 11/70 reads (16%) | PolyPhen possibly damaging (0.549); catalogued as rs372927085, COSV60403482; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZC3H14 | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.647); catalogued as COSV99192956; called by muse, mutect2, varscan2
- ZIM3 | c.972A>C p.K324N | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.898); catalogued as COSV99517631; called by muse, mutect2
- AFAP1L2 | c.1136del p.H379Pfs*91 | Frame Shift Del (DEL) | VAF 5/34 reads (15%) | called by mutect2, pindel, varscan2
- FCGBP | c.7000+1G>A p.X2334_splice | Splice Site (SNP) | VAF 41/814 reads (5%) | called by muse, mutect2
- GET4 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RAB3GAP1 | c.936dup p.R313* | Frame Shift Ins (INS) | VAF 25/109 reads (23%) | called by mutect2, pindel, varscan2
- EEA1 | c.690G>A p.L230= | Silent (SNP) | VAF 224/541 reads (41%) | catalogued as COSV100467054; called by muse, mutect2, varscan2
- FARP1 | c.1074G>A p.K358= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as COSV100129572; called by muse, mutect2, varscan2
- KRTAP6-1 | c.126C>T p.F42= | Silent (SNP) | VAF 27/117 reads (23%) | catalogued as COSV100228698, COSV58169100; called by muse, mutect2, varscan2
- MARCHF6 | c.2016C>A p.I672= | Silent (SNP) | VAF 10/220 reads (5%) | catalogued as COSV99929339; called by muse, mutect2
- MUC2 | c.1569C>T p.C523= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as rs370421370; called by muse, mutect2, varscan2
- PGLYRP2 | c.1515T>C p.S505= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV99483767; called by muse, varscan2
- PITPNM3 | c.888C>T p.I296= | Silent (SNP) | VAF 15/97 reads (15%) | catalogued as rs778461010, COSV99337908; called by muse, mutect2, varscan2
- PXDNL | c.2583C>G p.L861= | Silent (SNP) | VAF 59/105 reads (56%) | catalogued as COSV100681329; called by muse, mutect2, varscan2
- PXDNL | c.2292C>T p.P764= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV100681334; called by muse, varscan2
- SECISBP2 | c.1854C>T p.H618= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as rs772522221, COSV100368500; called by muse, mutect2, varscan2
- SEMA5A | c.828G>T p.L276= | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as COSV101227057, COSV101228522; called by muse, mutect2
- TAS2R40 | c.900C>T p.N300= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV101282974; called by muse, mutect2
- UGGT2 | c.3780A>T p.P1260= | Silent (SNP) | VAF 28/142 reads (20%) | catalogued as COSV100948462; called by muse, mutect2, varscan2
- ULK1 | c.1581G>A p.E527= | Silent (SNP) | VAF 142/939 reads (15%) | catalogued as COSV100416493; called by muse, mutect2, varscan2
